Gene-level copy-number profile of tumor specimen C3L-03377-02 from CPTAC case C3L-03377, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.0 years (26,673 days).
Specimen C3L-03377-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 361a3e59-c796-4f44-825f-6fd61669e6dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03377-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/aef57f3a-e179-4e76-9745-14192ceb83ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 18; copy number 2: 5,430; copy number 3: 5,190; copy number 4: 33,894; copy number 5: 9,875; copy number 6: 1,838; copy number 7: 1,842; copy number 8: 63; copy number 9: 21; copy number 10: 179; copy number 11: 4; copy number 14: 2; copy number 16: 10.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–23,438,700, 14 genes (within-gene range 0–3): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 216 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,004,103–237,004,441, 1 gene, copy number 9: MT1HL1.
- chr7:1,614,590–1,747,954, 6 genes, copy number 11–14: TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:38,239,580–38,335,514, 15 genes, copy number 9: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:54,752,250–54,812,727, 2 genes, copy number 9: SEC61G, SEC61G-DT.
- chr7:143,132,077–143,184,435, 2 genes, copy number 10: PIP, TAS2R39.
- chr15:88,459,477–88,875,353, 14 genes, copy number 10: MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN.
- chr15:88,960,070–89,334,861, 11 genes, copy number 10 (within-gene range 10–15): KRT18P47, AC107954.1, AC013565.2, AC013565.1, AC013565.3, HMGB1P8, AC124068.1, RLBP1, FANCI, POLG, MIR6766.
- chr15:89,471,398–90,082,207, 32 genes, copy number 10–16: RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7.
- chr15:90,160,604–90,229,679, 3 genes, copy number 10: SEMA4B, RN7SL346P, RPS12P26.
- chr15:90,234,200–90,717,141, 25 genes, copy number 9–16 (within-gene range 5–16): AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585.
- chr17:29,197,071–29,930,276, 29 genes, copy number 10 (within-gene range 2–10): AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70.
- chr17:35,400,878–36,457,535, 76 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
